Somatic mutation profile of tumor specimen TCGA-KS-A41I-01A (aliquot TCGA-KS-A41I-01A-11D-A23M-08) from TCGA case TCGA-KS-A41I, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 47.1 years (17,196 days).
Specimen TCGA-KS-A41I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 16962b60-b38e-438b-b29e-6c57b8a330f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KS-A41I-11A (Solid Tissue Normal), aliquot TCGA-KS-A41I-11A-11D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea893e8a-7f8f-4fb2-94d1-814b761da626

The open-access MAF lists 10 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 8, Frame Shift Del 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 72/194 reads (37%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCD1 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.051); catalogued as rs782723557, COSV54387635; called by muse, mutect2
- ALOX5 | c.711C>G p.F237L | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as COSV100980158; called by muse, mutect2, varscan2
- CYP11B1 | c.868G>A p.V290M | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0.167); catalogued as rs763444205, COSV52831026; called by muse, mutect2, varscan2
- KIAA1109 | c.8383C>G p.L2795V | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99169889; called by muse, mutect2, varscan2
- PLA2G4D | c.163C>A p.P55T | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.029); catalogued as COSV99299968; called by muse, mutect2
- PPP2R2B | c.241G>A p.D81N (on ENST00000394409; = p.D147N on NM_181674.2) | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1276618139, COSV60754854; called by muse, mutect2, varscan2
- TCTN2 | c.1391C>T p.S464L | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs991572501, COSV100315344; called by muse, mutect2, varscan2
- MAST4 | c.4095_4114del p.G1366Qfs*85 (on ENST00000403625 / NM_001164664.2; = p.G1177Qfs*85 on NM_015183.3) | Frame Shift Del (DEL) | VAF 33/157 reads (21%) | called by mutect2, pindel
- HECTD4 | c.7048T>C p.L2350= | Silent (SNP) | VAF 22/93 reads (24%) | catalogued as COSV101108292; called by muse, mutect2, varscan2
